Somatic mutation profile of tumor specimen TCGA-UF-A71B-01A (aliquot TCGA-UF-A71B-01A-12D-A34J-08) from TCGA case TCGA-UF-A71B, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 50.4 years (18,404 days).
Specimen TCGA-UF-A71B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fa5ada8-915a-4210-9d21-f317b8448a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A71B-10B (Blood Derived Normal), aliquot TCGA-UF-A71B-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9b3476d-17ad-46a7-8dd2-0cddf8be41b4

The open-access MAF lists 153 somatic variants for this specimen: 108 protein-altering or splice-affecting, 43 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 43, Nonsense Mutation 9, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, 3'Flank 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D2A | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs757208121, CM163041, COSV101052736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 30/306 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67960056, COSV67960150; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63659758; called by muse, mutect2, varscan2
- AL592490.1 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101308142; called by muse, mutect2, varscan2
- AMPH | c.1119C>G p.H373Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV100341667; called by muse, mutect2, varscan2
- AOPEP | c.1786C>T p.L596F (on ENST00000375315 / NM_001193329.1; = p.L497F on NM_032823.5) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs563124736, COSV99949388; called by muse, mutect2, varscan2
- APOB | c.10759G>A p.A3587T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99264954; called by muse, mutect2, varscan2
- AQP12B | c.505C>T p.R169W (on ENST00000621682; = p.R181W on NM_001102467.2) | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs766899986, COSV101315862; called by muse, varscan2
- ARHGAP32 | c.2590C>T p.P864S (on ENST00000310343 / NM_001378025.1; = p.P515S on NM_014715.4) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100087478; called by muse, mutect2, varscan2
- ART4 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966878; called by muse, mutect2, varscan2
- ATP10D | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as COSV99905461; called by muse, mutect2, varscan2
- BORA | c.995G>C p.S332T (on ENST00000613797; = p.S257T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); catalogued as COSV100909672; called by muse, mutect2, varscan2
- BPIFB2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as COSV99401333; called by muse, mutect2, varscan2
- C10orf71 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV60506824; called by muse, mutect2, varscan2
- C4B | c.4007G>T p.R1336L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs575175886; called by mutect2, varscan2
- CACNG8 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV99554944; called by muse, mutect2, varscan2
- CDK5 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52523107; called by muse, mutect2, varscan2
- COL14A1 | c.3123G>A p.W1041* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | catalogued as rs754773022, COSV52855054; called by muse, mutect2, varscan2
- COL16A1 | c.2503G>A p.V835M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs771923747, COSV99594134; called by muse, mutect2, varscan2
- COL22A1 | c.4225G>T p.G1409* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV57343254, COSV57345159; called by muse, mutect2, varscan2
- CSTF1 | c.415A>T p.R139W | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99410142; called by muse, mutect2, varscan2
- CTPS2 | c.278T>C p.I93T | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100826773; called by muse, mutect2, varscan2
- CUL3 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV100024093; called by muse, mutect2, varscan2
- CYFIP2 | c.373T>C p.F125L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as COSV100556355; called by muse, mutect2, varscan2
- DCAF17 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100266069; called by muse, mutect2, varscan2
- DDX5 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as rs1488604088, COSV56749954; called by muse, mutect2, varscan2
- DHODH | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99536834; called by muse, mutect2, varscan2
- DSEL | c.1366T>A p.Y456N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100025522; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100348988; called by muse, mutect2, varscan2
- EPHB3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs373788594; called by muse, mutect2
- EPS8L1 | c.871G>A p.G291S (on ENST00000201647 / NM_133180.3; = p.G164S on NM_017729.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99136001; called by muse, mutect2, varscan2
- ERBIN | c.3044G>T p.S1015I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99396525; called by muse, mutect2, varscan2
- FBN2 | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs370804151, COSV52543595; called by mutect2, varscan2
- FOCAD | c.3274G>T p.A1092S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100620274; called by muse, mutect2, varscan2
- GAD1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as COSV100713796; called by muse, mutect2, varscan2
- GALNT13 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV101222602, COSV67215270, COSV67240330; called by muse, mutect2, varscan2
- GDA | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs755276696, COSV52992005, COSV52999666; called by muse, mutect2, varscan2
- GOPC | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV99270864; called by muse, mutect2
- GPC3 | c.336A>G p.Q112= | Splice Region (SNP) | VAF 90/250 reads (36%) | catalogued as COSV100892925, COSV63672057; called by muse, mutect2, varscan2
- GPR139 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100429795; called by muse, mutect2, varscan2
- HCAR2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs769559044, COSV100186467; called by muse, mutect2, varscan2
- HEXIM2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56235993; called by muse, mutect2, varscan2
- ICE1 | c.2597G>C p.R866T | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV56830351, COSV99664380; called by muse, mutect2, varscan2
- IGKV3D-20 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs778572038; called by muse, mutect2
- INSIG1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV100452945; called by muse, mutect2, varscan2
- KIF4B | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV70532395; called by muse, mutect2, varscan2
- KLHL23 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV99775682; called by muse, mutect2, varscan2
- KRT34 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.086); catalogued as COSV101222598; called by muse, mutect2, varscan2
- KRTAP5-3 | c.683G>C p.C228S | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101294501; called by muse, varscan2
- LCA5L | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs777886716, COSV99903564; called by muse, mutect2, varscan2
- LGI1 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV101004390; called by muse, mutect2
- LIFR | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV99663853; called by muse, mutect2, varscan2
- LRP2 | c.4987C>A p.R1663S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55553067, COSV99787664; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs938340943, COSV99151189; called by muse, mutect2, varscan2
- MCM3AP | c.5074T>G p.Y1692D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99386775; called by muse, mutect2, varscan2
- MN1 | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs757899030, COSV100179768; called by muse, mutect2, varscan2
- MOGS | c.1562A>C p.H521P | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.569); catalogued as COSV99270452; called by muse, mutect2, varscan2
- MYH7 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as COSV62516208; called by muse, mutect2, varscan2
- NCAPD3 | c.4255A>T p.S1419C | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1400370816, COSV100138006; called by muse, mutect2, varscan2
- NFRKB | c.2931G>A p.M977I (on ENST00000446488 / NM_001143835.2; = p.M1002I on NM_006165.3) | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs777408177, COSV100451863; called by muse, mutect2, varscan2
- NPAP1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 73/314 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.049); catalogued as COSV100275146; called by muse, mutect2, varscan2
- NSD1 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1428724191, CD051767, COSV100728777; called by muse, mutect2, varscan2
- OR5AS1 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1212388759, COSV100546238; called by muse, mutect2, varscan2
- PABPC5 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs367670485, COSV100442277; called by muse, mutect2, varscan2
- PAX5 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100814193; called by muse, mutect2, varscan2
- PCCA | c.1364A>G p.Y455C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1377013894, COSV100886746; called by muse, mutect2, varscan2
- PCDHB13 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV99507121; called by muse, mutect2, varscan2
- PDE3A | c.3335C>G p.S1112C | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1057135686, COSV100762032; called by muse, mutect2, varscan2
- PHIP | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99243825; called by muse, mutect2, varscan2
- PIGQ | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV99215946; called by muse, mutect2, varscan2
- PIKFYVE | c.2303G>T p.G768V | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010388; called by muse, mutect2, varscan2
- POU6F2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV101302597, COSV68880402; called by muse, mutect2, varscan2
- PROCA1 | c.469G>A p.A157T (on ENST00000439862 / NM_001366301.1; = p.A129T on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV99972632; called by muse, mutect2, varscan2
- PSG3 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.704); catalogued as COSV100548858; called by muse, mutect2, varscan2
- PTPRB | c.4450G>A p.A1484T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54234416, COSV99716867; called by muse, mutect2, varscan2
- PURG | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs765564331, COSV53305774; called by muse, mutect2, varscan2
- QSOX2 | c.787A>T p.I263F | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100699743; called by muse, mutect2, varscan2
- RFXAP | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV99715148; called by muse, mutect2, varscan2
- RIC3 | c.1037G>T p.G346V (on ENST00000309737 / NM_001206671.4; = p.G345V on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.369); catalogued as COSV58302119; called by muse, mutect2, varscan2
- ROR2 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100995724; called by muse, mutect2, varscan2
- ROS1 | c.1469T>C p.I490T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100876905; called by muse, mutect2, varscan2
- SENP6 | c.147-1G>A p.X49_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100519094; called by muse, mutect2, varscan2
- SIAH3 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101247810; called by muse, mutect2
- SLC13A3 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99286499; called by muse, mutect2, varscan2
- SLC29A2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 34/669 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100237068; called by muse, mutect2
- SRRM4 | c.902C>A p.S301* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99938265; called by muse, mutect2, varscan2
- TAS2R40 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV101282988; called by muse, mutect2, varscan2
- TBX22 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776905471, COSV100960729, COSV64785115; called by mutect2, varscan2
- TMX4 | c.635A>C p.E212A | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99851463; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs764468530, COSV50554422; called by muse, mutect2, varscan2
- TUT4 | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1338515678, COSV57115137; called by muse, mutect2
- TYRO3 | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99777478; called by muse, mutect2, varscan2
- UNK | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs374489352; called by muse, mutect2, varscan2
- WHRN | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99470104; called by muse, mutect2, varscan2
- WIPI1 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs749738363, COSV100048358; called by muse, mutect2, varscan2
- XIRP2 | c.4118T>C p.I1373T (on ENST00000628543; = p.I1548T on NM_152381.6) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV54689256, COSV99741368; called by muse, mutect2
- ZNF398 | c.1178C>G p.A393G (on ENST00000475153 / NM_170686.3; = p.A222G on NM_020781.4) | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100246876, COSV60065720; called by muse, mutect2, varscan2
- ZNF441 | c.2012A>G p.Y671C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs138221659; called by muse, mutect2, varscan2
- ZNF594 | c.1262G>C p.R421T | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV101280452, COSV68385201; called by muse, mutect2, varscan2
- ZNF682 | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100653239; called by muse, mutect2, varscan2
- ZNF718 | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV101210249; called by muse, mutect2, varscan2
- APAF1 | c.327del p.Y109* | Frame Shift Del (DEL) | VAF 21/126 reads (17%) | called by mutect2, pindel, varscan2
- CACTIN | c.1231_1232del p.Y411Qfs*44 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ISM2 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO19 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4Q3 | c.127dup p.Y43Lfs*37 | Frame Shift Ins (INS) | VAF 22/162 reads (14%) | called by mutect2, varscan2
- SRSF2 | c.21_22dup p.P8Lfs*7 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- ADAMTSL1 | c.1989G>A p.L663= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99442066; called by muse, mutect2, varscan2
- ADGRA1 | c.1215T>G p.S405= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100811013; called by muse, mutect2, varscan2
- ARHGAP4 | c.792C>T p.D264= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as rs1557104716, COSV63134042; called by muse, mutect2, varscan2
- BCR | c.1638C>A p.I546= | Silent (SNP) | VAF 79/170 reads (46%) | catalogued as COSV100006346; called by muse, mutect2, varscan2
- CACNG7 | c.78C>T p.I26= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1368009098, COSV99711943; called by muse, mutect2, varscan2
- COBLL1 | c.1710A>G p.V570= (on ENST00000392717; = p.V532= on NM_014900.5) | Silent (SNP) | VAF 53/226 reads (23%) | catalogued as rs1364756788, COSV99527708; called by muse, mutect2, varscan2
- COL18A1 | c.4824G>A p.A1608= (on ENST00000359759 / NM_130444.3; = p.A1373= on NM_030582.4) | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs372559352; ClinVar: likely benign; called by muse, varscan2
- CPO | c.546C>A p.L182= | Silent (SNP) | VAF 63/267 reads (24%) | catalogued as COSV99786440; called by muse, mutect2
- CTNND2 | c.2910G>C p.V970= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV100474932, COSV58890575; called by muse, mutect2
- DAB1 | c.1251C>T p.L417= (on ENST00000371231; = p.L384= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100976260, COSV64692542; called by muse, mutect2, varscan2
- DMXL2 | c.33C>T p.V11= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs887564303, COSV51847013, COSV99196213; called by muse, mutect2
- FBXO3 | c.1215A>G p.T405= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV99682156; called by muse, mutect2, varscan2
- FGD2 | c.315G>A p.K105= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99236055; called by muse, mutect2, varscan2
- FGD6 | c.1260A>G p.K420= | Silent (SNP) | VAF 58/200 reads (29%) | catalogued as COSV100676505; called by muse, mutect2, varscan2
- GABRA4 | c.459A>G p.R153= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1309324349, COSV99973865; called by muse, mutect2, varscan2
- GALK2 | c.496C>T p.L166= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100508807; called by muse, mutect2, varscan2
- HIRA | c.498T>A p.I166= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99600152; called by muse, mutect2, varscan2
- HMCN1 | c.3138T>C p.S1046= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV54877097; called by muse, mutect2, varscan2
- LAMA2 | c.9114G>A p.E3038= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV101370344; called by muse, mutect2, varscan2
- LINGO2 | c.609C>A p.L203= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100430450; called by muse, mutect2, varscan2
- MTG2 | c.1119G>A p.L373= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV63694671; called by muse, mutect2
- MUC3A | c.7191C>T p.T2397= | Silent (SNP) | VAF 87/350 reads (25%) | catalogued as rs1193630496; called by muse, mutect2, varscan2
- NADSYN1 | c.69G>A p.L23= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100034621; called by muse, mutect2, varscan2
- NPHP4 | c.3153C>A p.L1051= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1325345485, COSV100976832; called by muse, mutect2, varscan2
- NUP153 | c.219C>T p.S73= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs1295011678, COSV50454043; called by muse, mutect2, varscan2
- OR2W3 | c.120A>C p.V40= | Silent (SNP) | VAF 97/272 reads (36%) | catalogued as COSV100831654, COSV100831783; called by muse, mutect2, varscan2
- OR5T1 | c.927A>G p.V309= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV100478886; called by muse, mutect2, varscan2
- PCDHGC5 | c.2295G>A p.R765= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99339375; called by muse, mutect2, varscan2
- PEAK1 | c.5133G>C p.L1711= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV100432808; called by muse, mutect2, varscan2
- PIK3R5 | c.2076C>A p.I692= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99353172; called by muse, mutect2, varscan2
- PRB3 | c.7C>T p.L3= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs768661875, COSV99685670; called by muse, mutect2, varscan2
- RNF19A | c.603C>T p.Y201= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as rs568403328, COSV61993448; called by muse, mutect2, varscan2
- RPTN | c.882C>T p.H294= | Silent (SNP) | VAF 193/770 reads (25%) | catalogued as COSV100285421; called by muse, mutect2, varscan2
- RSF1 | c.3399G>A p.P1133= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs920477732, COSV100407072; called by muse, mutect2, varscan2
- RTN4RL1 | c.876C>T p.D292= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100486523; called by muse, mutect2, varscan2
- SFTPA1 | c.36G>A p.L12= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as COSV100956981; called by muse, mutect2
- SFTPA2 | c.36G>A p.L12= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as COSV64882645; called by muse, mutect2, varscan2
- SHROOM4 | c.2385T>C p.H795= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as COSV99173249; called by muse, mutect2, varscan2
- TACC2 | c.2382G>C p.T794= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100552091, COSV100554501; called by muse, mutect2, varscan2
- USH2A | c.5478C>T p.S1826= | Silent (SNP) | VAF 34/350 reads (10%) | catalogued as rs769191074, COSV56325193; called by muse, mutect2
- ZFAT | c.1860C>T p.H620= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs1244352544, COSV100914455; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1605A>G p.Q535= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs750063211, COSV100362865; called by muse, mutect2
- ZNF746 | c.396G>A p.L132= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as COSV100502415; called by muse, mutect2, varscan2
- ARRDC1 | chr9:137616011 del CCA | 3'Flank (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel
- GATA3 | chr10:8051031 T>C | 5'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
